Somatic mutation profile of tumor specimen TCGA-34-A5IX-01A (aliquot TCGA-34-A5IX-01A-12D-A27K-08) from TCGA case TCGA-34-A5IX, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 80.5 years (29,391 days).
Specimen TCGA-34-A5IX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9c7bb1b-fb47-495f-8c37-da7ff3a02f5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-A5IX-10A (Blood Derived Normal), aliquot TCGA-34-A5IX-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/714691b3-d4fb-4111-b78d-42585410a4db

The open-access MAF lists 308 somatic variants for this specimen: 238 protein-altering or splice-affecting, 60 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 200, Silent 60, Nonsense Mutation 14, Frame Shift Del 11, Splice Site 5, RNA 4, Translation Start Site 3, Splice Region 3, 3'UTR 3, In Frame Del 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 24/77 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1555526131, COSV52674926, COSV52693942, COSV52759722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB1 | c.1208C>G p.S403C | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99711998; called by muse, mutect2, varscan2
- ABCC4 | c.3530T>C p.F1177S | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100972200; called by muse, mutect2, varscan2
- ACTN4 | c.188A>T p.H63L | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV99399716; called by muse, mutect2, varscan2
- ADAM18 | c.1076A>G p.N359S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.177); catalogued as COSV99694762; called by muse, mutect2, varscan2
- ADAMTS12 | c.4088G>T p.R1363L | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100710198; called by muse, mutect2, varscan2
- ADGRL3 | c.918G>T p.K306N (on ENST00000506720 / NM_001322402.2; = p.K238N on NM_015236.6) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101546824, COSV72273095; called by muse, mutect2, varscan2
- AHNAK2 | c.6972G>T p.K2324N | Missense Mutation (SNP) | VAF 119/360 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100315272; called by muse, mutect2, varscan2
- AK5 | c.114G>C p.L38F (on ENST00000354567 / NM_174858.3; = p.L12F on NM_012093.4) | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100481326; called by muse, mutect2, varscan2
- ALS2 | c.553A>T p.T185S | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.134); catalogued as CD054292, COSV99968642; called by muse, mutect2, varscan2
- ANKRD17 | c.6637A>G p.S2213G | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.023); catalogued as rs1183043035, COSV100428462; called by muse, mutect2, varscan2
- ARHGAP35 | c.2064del p.R689Gfs*5 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as COSV68329019; called by mutect2, pindel, varscan2
- ASAP2 | c.2429T>C p.V810A | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV99855667; called by muse, mutect2, varscan2
- ASTN1 | c.32C>A p.A11D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); catalogued as COSV99920293; called by muse, mutect2, varscan2
- ASXL3 | c.6586C>T p.P2196S | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.945); catalogued as COSV99323122, COSV99325899; called by muse, mutect2, varscan2
- AXIN1 | c.1528G>T p.A510S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV51989277, COSV51990130; called by muse, mutect2
- BTN1A1 | c.1281C>G p.D427E | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV99764132; called by muse, mutect2
- C1QTNF8 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV100116328; called by muse, mutect2
- C2orf78 | c.688G>T p.G230C | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV101280892; called by muse, mutect2, varscan2
- CACNA1B | c.3555C>A p.Y1185* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99494965; called by muse, mutect2, varscan2
- CACNG2 | c.965C>A p.P322H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100268446; called by muse, mutect2, varscan2
- CAVIN2 | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100414019; called by muse, mutect2, varscan2
- CCN4 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs375956639, COSV99136938; called by muse, mutect2, varscan2
- CCR2 | c.1000G>T p.G334C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.43); catalogued as COSV99431945; called by muse, mutect2, varscan2
- CCR2 | c.1001G>T p.G334V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99431947; called by muse, mutect2, varscan2
- CD300C | c.251T>A p.I84N | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58170960; called by muse, mutect2, varscan2
- CD6 | c.911A>T p.Q304L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV100532760; called by muse, mutect2, varscan2
- CDH12 | c.1829T>C p.V610A | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.185); catalogued as rs749280570, COSV101201072; called by muse, mutect2, varscan2
- CDH9 | c.1791G>T p.M597I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99141377; called by muse, mutect2, varscan2
- CGN | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as COSV54967957, COSV99641820; called by muse, mutect2, varscan2
- CLN8 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs775174607, COSV100485964; called by muse, mutect2, varscan2
- CLRN2 | c.38C>A p.A13E | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV55551458, COSV99845656; called by muse, mutect2, varscan2
- CNBD1 | c.1087A>T p.N363Y | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV101582152; called by muse, varscan2
- CNKSR3 | c.629A>G p.E210G | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV101401276; called by muse, mutect2, varscan2
- CNRIP1 | c.299G>C p.G100A | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99721101; called by muse, mutect2, varscan2
- CNTNAP5 | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV101442982; called by muse, mutect2, varscan2
- COG4 | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1450741267, COSV100091195; called by muse, mutect2, varscan2
- COL12A1 | c.5622C>G p.Y1874* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100485297; called by muse, mutect2, varscan2
- COL4A2 | c.1777-1G>T p.X593_splice | Splice Site (SNP) | VAF 9/112 reads (8%) | catalogued as COSV100847165; called by muse, mutect2
- COL4A2 | c.1979-1G>T p.X660_splice | Splice Site (SNP) | VAF 12/165 reads (7%) | catalogued as COSV100847166; called by muse, mutect2
- CPA3 | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV99935922; called by muse, mutect2, varscan2
- CPB1 | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV99294077; called by muse, mutect2, varscan2
- CPLX2 | c.262C>A p.Q88K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.049); catalogued as COSV100852999; called by muse, mutect2, varscan2
- CR1 | c.97C>A p.L33M | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100887363; called by muse, mutect2, varscan2
- CRB1 | c.2679C>T p.S893= | Splice Region (SNP) | VAF 10/194 reads (5%) | catalogued as COSV100957635; called by muse, mutect2
- CREBRF | c.27G>C p.M9I | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV99755273; called by muse, mutect2, varscan2
- CRTAM | c.678T>A p.D226E | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99911728; called by muse, mutect2, varscan2
- CSGALNACT1 | c.568A>G p.T190A | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV100174466; called by muse, mutect2, varscan2
- CSMD3 | c.6062C>T p.T2021M (on ENST00000297405 / NM_001363185.1; = p.T1917M on NM_052900.3) | Missense Mutation (SNP) | VAF 60/97 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs1429656861, COSV52129054, COSV52348103; called by muse, mutect2, varscan2
- CSRNP1 | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV99826670; called by muse, mutect2, varscan2
- CTSC | c.570C>A p.Y190* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99910460; called by muse, mutect2, varscan2
- CYTIP | c.280-2A>G p.X94_splice | Splice Site (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99938615; called by muse, mutect2, varscan2
- DMP1 | c.200G>T p.S67I | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV99218463; called by muse, mutect2
- DMRTA2 | c.1428C>A p.H476Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV101288827; called by muse, mutect2, varscan2
- DNAH7 | c.9317C>A p.T3106N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs570476938, COSV100413687; called by muse, varscan2
- DSC1 | c.2122C>G p.L708V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV57141917, COSV99937099; called by mutect2, varscan2
- DYRK3 | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV100895580; called by muse, mutect2, varscan2
- DYSF | c.2825T>A p.M942K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99243936; called by muse, mutect2, varscan2
- EDC3 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.789); catalogued as COSV100165746; called by muse, mutect2, varscan2
- EEF2 | c.2518A>T p.K840* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100500542; called by mutect2, varscan2
- EHD3 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs771567803, COSV59029851; called by muse, mutect2, varscan2
- EIF2AK1 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 74/232 reads (32%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.695); catalogued as rs756091057, COSV99551403; called by muse, mutect2, varscan2
- EIF4G3 | c.3605-1G>A p.X1202_splice | Splice Site (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99943032; called by muse, mutect2, varscan2
- ERICH3 | c.4412C>A p.A1471D | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs767540585, COSV58609965; called by muse, mutect2, varscan2
- FABP1 | c.336C>A p.T112= | Splice Region (SNP) | VAF 12/66 reads (18%) | catalogued as COSV55557986; called by muse, mutect2, varscan2
- FBXL16 | c.227C>A p.P76Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100178691; called by muse, mutect2, varscan2
- FERMT2 | c.2018A>T p.Y673F | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV100448632; called by muse, mutect2, varscan2
- FGFRL1 | c.1424A>G p.Y475C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99294404; called by muse, mutect2, varscan2
- FYN | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 62/228 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1230972545, COSV99991053; called by muse, mutect2, varscan2
- GAB4 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV101271866, COSV68753910; called by muse, mutect2, varscan2
- GALM | c.167T>C p.V56A | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); catalogued as COSV99696940; called by muse, mutect2, varscan2
- GCDH | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99535671; called by muse, mutect2, varscan2
- GFI1 | c.949T>A p.C317S | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99647364; called by muse, mutect2, varscan2
- GHR | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.401); catalogued as COSV100049749; called by muse, mutect2, varscan2
- GIMAP1 | c.30A>T p.E10D | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.45); catalogued as COSV100211911; called by muse, mutect2, varscan2
- GJD4 | c.394G>C p.G132R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV100397066, COSV100397374; called by muse, mutect2
- GLB1L2 | c.362T>C p.V121A | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV100335106; called by muse, mutect2, varscan2
- GPAT3 | c.645G>T p.K215N | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100022680; called by muse, mutect2
- GPR155 | c.1380G>A p.W460* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV99789644; called by muse, mutect2, varscan2
- GPR32 | c.1048C>A p.R350S | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0.015); catalogued as COSV99567176; called by muse, mutect2, varscan2
- GPR83 | c.974C>G p.A325G | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.078); catalogued as COSV99703536; called by muse, mutect2, varscan2
- GPRIN3 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs748038123, COSV100310553; called by muse, mutect2, varscan2
- GPSM3 | c.206T>A p.V69E | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100900326; called by muse, mutect2, varscan2
- GRIK1 | c.2753T>A p.V918E | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); catalogued as COSV100515758; called by muse, mutect2, varscan2
- GRIK2 | c.1372C>T p.R458* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as rs1271066576, COSV59710025; called by muse, mutect2, varscan2
- HBE1 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs1359024092; called by mutect2, varscan2
- HK3 | c.1758C>A p.D586E | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0.028); catalogued as COSV99457723; called by muse, mutect2, varscan2
- HNRNPA0 | c.167C>A p.S56Y | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100152869; called by muse, mutect2, varscan2
- IGF2 | c.126G>T p.E42D | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV56101792; called by muse, mutect2, varscan2
- IKZF3 | c.632A>G p.Y211C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99499168; called by muse, mutect2, varscan2
- JAGN1 | c.43A>G p.S15G | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs943577194, COSV100314687; called by muse, mutect2, varscan2
- JAM2 | c.149G>A p.C50Y | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100467763, COSV57256886; called by muse, mutect2, varscan2
- JARID2 | c.1966G>T p.A656S | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.383); catalogued as COSV100521210; called by muse, mutect2, varscan2
- KCNA6 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99768289; called by muse, mutect2, varscan2
- KCNK9 | c.68C>A p.A23D | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100270220; called by muse, mutect2, varscan2
- KIF1A | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs374011613; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF25 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs148907230; called by muse, mutect2, varscan2
- KIZ | c.814G>C p.A272P | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.139); catalogued as COSV99851808; called by muse, mutect2, varscan2
- KYNU | c.1127A>G p.Y376C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV51594811; called by muse, mutect2, varscan2
- LAIR1 | c.306C>G p.I102M | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.361); catalogued as COSV100479393; called by muse, mutect2, varscan2
- LHX8 | c.833C>G p.A278G | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99633020; called by muse, mutect2
- LIG4 | c.1136A>G p.H379R | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100799675; called by muse, mutect2, varscan2
- LOXL4 | c.2005G>C p.G669R | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99583557, COSV99584121; called by muse, mutect2, varscan2
- LRP1B | c.7002G>C p.W2334C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101251587; called by muse, mutect2
- LRRIQ1 | c.3139A>T p.I1047F | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101279380; called by muse, mutect2, varscan2
- MADD | c.1174G>T p.D392Y | Missense Mutation (SNP) | VAF 65/184 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100210929; called by muse, mutect2, varscan2
- MADD | c.3944C>G p.S1315C | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100210930; called by muse, mutect2, varscan2
- MBP | c.416G>T p.R139I (on ENST00000355994 / NM_001025101.2; = p.R6I on NM_002385.3) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV100592408; called by muse, mutect2, varscan2
- MDN1 | c.5627G>T p.G1876V | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101020710; called by muse, mutect2, varscan2
- MED25 | c.2071T>A p.L691M | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.36); catalogued as COSV100457024; called by muse, mutect2, varscan2
- MEPE | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | catalogued as COSV100734834; called by muse, mutect2, varscan2
- MIB2 | c.2618T>C p.L873P | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.943); catalogued as COSV100598661; called by muse, mutect2
- MIOS | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100402528; called by muse, mutect2
- MME | c.1700C>A p.A567D | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.421); catalogued as rs202024179, COSV100852203; called by muse, mutect2, varscan2
- MMRN1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 23/84 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV53341284, COSV99306346; called by muse, mutect2, varscan2
- MORC1 | c.1631A>T p.K544I | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV99224938; called by muse, mutect2, varscan2
- MPO | c.1880C>T p.A627V | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs751922909, COSV51857046, COSV51860455; called by muse, mutect2, varscan2
- MRGPRX2 | c.903G>T p.Q301H | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100316606, COSV61674716; called by muse, mutect2, varscan2
- MTF2 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV100940040; called by muse, mutect2, varscan2
- MTUS1 | c.118T>C p.S40P | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100028780; called by muse, mutect2, varscan2
- MYLK | c.2609G>C p.R870P | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100658445, COSV60607894; called by muse, mutect2, varscan2
- NAV1 | c.4249G>C p.E1417Q | Missense Mutation (SNP) | VAF 65/231 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as COSV99818099; called by muse, mutect2, varscan2
- NCAPH2 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100237851; called by muse, mutect2, varscan2
- NEDD4 | c.2487G>C p.Q829H (on ENST00000508342 / NM_001284338.1; = p.Q410H on NM_006154.4) | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.396); catalogued as COSV100163236; called by muse, mutect2, varscan2
- NKX2-4 | c.1024G>T p.G342C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV100698563; called by muse, mutect2
- NLGN1 | c.1639G>T p.A547S | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV100848716; called by muse, mutect2, varscan2
- NLRP3 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60225120; called by muse, mutect2, varscan2
- NLRP6 | c.2077C>G p.R693G | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100380918; called by muse, mutect2, varscan2
- NLRP9 | c.1235A>T p.H412L | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as COSV100242504; called by muse, mutect2, varscan2
- NLRP9 | c.1234C>A p.H412N | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as COSV100242505; called by muse, mutect2, varscan2
- NOTCH2 | c.4732C>T p.R1578C | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.927); catalogued as rs775412281, COSV56705942; called by muse, mutect2, varscan2
- NRXN2 | c.2039T>C p.V680A | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99632306; called by muse, mutect2, varscan2
- NRXN2 | c.1602G>T p.Q534H | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99632310; called by muse, mutect2, varscan2
- OLFML2A | c.937A>T p.T313S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.026); catalogued as COSV99992341; called by muse, mutect2, varscan2
- OLIG2 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV100324175; called by muse, mutect2
- OR10K1 | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.456); catalogued as COSV99193198; called by muse, mutect2, varscan2
- OR2AE1 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as COSV100318270; called by muse, mutect2, varscan2
- OR2AT4 | c.84C>A p.F28L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100532256; called by muse, mutect2, varscan2
- OR2V2 | c.349G>C p.G117R | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100079986; called by muse, mutect2, varscan2
- OR4D5 | c.635T>C p.L212P | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV58306063, COSV58307098; called by muse, mutect2, varscan2
- OR8J3 | c.236C>G p.P79R | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100040502, COSV100040802; called by muse, mutect2, varscan2
- PAH | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV61019371; called by muse, mutect2, varscan2
- PBX1 | c.784A>G p.S262G | Missense Mutation (SNP) | VAF 55/228 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV100904920; called by muse, mutect2, varscan2
- PCDH11Y | c.3086C>T p.P1029L (on ENST00000400457 / NM_032973.2; = p.P1018L on NM_032971.3) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as COSV99290429; called by muse, mutect2, varscan2
- PCDH15 | c.3894T>A p.F1298L | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV100214451; called by muse, mutect2, varscan2
- PCDHB12 | c.1626C>G p.S542R | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99506628; called by muse, mutect2, varscan2
- PCDHB8 | c.455C>A p.A152E | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as COSV50765193, COSV50783605; called by muse, mutect2, varscan2
- PCDHGA5 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.166); catalogued as rs868142397, COSV53908755; called by muse, mutect2, varscan2
- PDYN | c.721C>G p.Q241E | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99452627; called by muse, mutect2, varscan2
- PDZD2 | c.1820G>C p.C607S | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0.228); catalogued as COSV99223513; called by muse, mutect2, varscan2
- PEG3 | c.3370G>T p.D1124Y | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55646223, COSV99686975; called by muse, mutect2, varscan2
- PIGK | c.945G>T p.E315D | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1468252637, COSV100769780; called by muse, mutect2, varscan2
- PLEKHG2 | c.564C>G p.I188M | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99216736; called by muse, mutect2, varscan2
- POM121L12 | c.56del p.G19Efs*15 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as COSV68692587; called by mutect2, pindel
- POU6F2 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as COSV101302396; called by muse, mutect2, varscan2
- PPFIA2 | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100331488; called by muse, mutect2, varscan2
- PREPL | c.8A>G p.Q3R | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.953); catalogued as COSV99575885; called by muse, mutect2, varscan2
- PRRC2A | c.586G>T p.G196* | Nonsense Mutation (SNP) | VAF 17/97 reads (18%) | catalogued as COSV100784517, COSV100784573; called by muse, mutect2, varscan2
- PRSS58 | c.392C>A p.T131N | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV73488517, COSV73488787; called by muse, mutect2, varscan2
- PRX | c.1570A>G p.K524E | Missense Mutation (SNP) | VAF 58/308 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV99397379; called by muse, varscan2
- PTPRR | c.1139G>C p.R380T | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV99316018; called by muse, mutect2, varscan2
- PUS7 | c.841A>C p.R281= | Splice Region (SNP) | VAF 38/154 reads (25%) | catalogued as COSV100708413; called by muse, varscan2
- QPRT | c.152C>A p.P51H | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); catalogued as COSV99568871; called by muse, mutect2, varscan2
- R3HDML | c.675C>A p.C225* | Nonsense Mutation (SNP) | VAF 28/103 reads (27%) | catalogued as COSV99406991; called by muse, mutect2, varscan2
- RASAL3 | c.1678A>T p.N560Y | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV100640258; called by muse, mutect2, varscan2
- RBM39 | c.51+1G>T p.X17_splice | Splice Site (SNP) | VAF 14/51 reads (27%) | catalogued as COSV99488212; called by muse, mutect2, varscan2
- RBM46 | c.1104C>A p.C368* | Nonsense Mutation (SNP) | VAF 25/75 reads (33%) | catalogued as COSV99907831; called by muse, mutect2, varscan2
- REV3L | c.4872T>A p.F1624L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV100724802; called by muse, mutect2, varscan2
- RFPL2 | c.878C>A p.P293Q | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99963971, COSV99964402; called by muse, mutect2, varscan2
- RNASEL | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 40/177 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as CM020299, COSV100842529; called by muse, mutect2, varscan2
- RNF25 | c.682A>T p.S228C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV99828800; called by muse, varscan2
- RP1L1 | c.3139G>T p.A1047S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV101222897; called by muse, mutect2, varscan2
- RYR2 | c.1603G>C p.E535Q | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV63658719, COSV63715396; called by muse, mutect2, varscan2
- SEMA3D | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 48/228 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs1309268425, COSV99405716; called by muse, mutect2, varscan2
- SEPTIN14 | c.86C>A p.T29K | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV101193176; called by muse, mutect2, varscan2
- SERF2 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.918); catalogued as COSV51049321; called by muse, mutect2
- SIGLEC6 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV58435341; called by muse, mutect2, varscan2
- SLC15A2 | c.1441G>T p.V481L | Missense Mutation (SNP) | VAF 27/257 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs762529664, COSV99815043; called by muse, mutect2, varscan2
- SLC25A17 | c.31G>T p.V11F | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV99610487; called by muse, mutect2, varscan2
- SLX4 | c.3005G>T p.S1002I | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.249); catalogued as COSV99567532; called by muse, mutect2, varscan2
- SMAP1 | c.1352G>A p.G451E (on ENST00000370455 / NM_001044305.3; = p.G424E on NM_021940.5) | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100016573; called by muse, mutect2, varscan2
- SNRNP200 | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs938097207, COSV100107042; called by muse, mutect2, varscan2
- SORCS3 | c.2330C>T p.P777L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100863366; called by muse, mutect2, varscan2
- SPRY1 | c.464G>T p.R155L | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV100201727, COSV59338388; called by muse, mutect2, varscan2
- STAB2 | c.194C>A p.S65Y | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV101185588; called by muse, mutect2, varscan2
- STK19 | c.622G>C p.D208H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100941607; called by muse, mutect2, varscan2
- STYXL2 | c.2967C>A p.D989E | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.152); catalogued as COSV99608502; called by muse, mutect2, varscan2
- TAOK3 | c.1997C>T p.T666M | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs373274877; called by muse, mutect2, varscan2
- TEX55 | c.1309C>A p.Q437K | Missense Mutation (SNP) | VAF 70/187 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.873); catalogued as rs754169437, COSV99817260; called by muse, mutect2, varscan2
- TG | c.3084G>T p.M1028I | Missense Mutation (SNP) | VAF 80/142 reads (56%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99598734; called by muse, mutect2
- TJP1 | c.3471C>G p.H1157Q | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.142); catalogued as rs370701172, COSV100632228; called by muse, mutect2, varscan2
- TMEM120A | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs368599599; called by muse, mutect2, varscan2
- TMEM126B | c.171A>G p.I57M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.187); catalogued as COSV100728968; called by muse, mutect2
- TMEM169 | c.475C>A p.H159N | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99824334; called by muse, mutect2, varscan2
- TMPRSS11B | c.996C>G p.N332K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as COSV100219214; called by muse, mutect2, varscan2
- TNRC18 | c.4481A>T p.Y1494F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101269522; called by muse, mutect2
- TNS1 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 70/267 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV99409722; called by muse, mutect2, varscan2
- TP53BP2 | c.1365G>T p.E455D (on ENST00000343537 / NM_001031685.3; = p.E326D on NM_005426.2) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100636493; called by muse, mutect2, varscan2
- TRBV6-1 | c.218C>A p.T73N | Missense Mutation (SNP) | VAF 57/306 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs774951062; called by muse, mutect2, varscan2
- TRHR | c.535T>A p.C179S | Missense Mutation (SNP) | VAF 54/93 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100304625; called by muse, mutect2, varscan2
- TSC2 | c.4874T>C p.M1625T | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99237051; called by muse, mutect2, varscan2
- TTN | c.101915C>G p.S33972C (on ENST00000591111; = p.S26548C on NM_003319.4) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | PolyPhen possibly damaging (0.794); catalogued as COSV100592210; called by muse, mutect2, varscan2
- TULP2 | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.312); catalogued as COSV99667636, COSV99667786; called by muse, mutect2, varscan2
- TUT4 | c.2429C>A p.P810Q | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99931703; called by muse, mutect2, varscan2
- UBXN2B | c.649G>T p.G217* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV101275562; called by muse, mutect2, varscan2
- ULK1 | c.500G>C p.G167A | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100416458; called by muse, mutect2
- ULK1 | c.1586G>T p.R529L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV100416459, COSV58858554; called by muse, mutect2, varscan2
- USH2A | c.11458G>C p.A3820P | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.105); catalogued as COSV100228321; called by muse, mutect2, varscan2
- USH2A | c.6034A>G p.T2012A | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as rs1190506266, COSV100243219, COSV56417549; called by muse, mutect2, varscan2
- USH2A | c.211G>C p.A71P | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100228323; called by muse, mutect2, varscan2
- USP13 | c.754A>G p.M252V | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as rs778998322, COSV99830666; called by muse, mutect2, varscan2
- USP26 | c.1840C>A p.Q614K | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.34); catalogued as COSV100896524; called by muse, mutect2, varscan2
- USP34 | c.571A>C p.S191R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.962); catalogued as COSV101276589; called by muse, mutect2, varscan2
- USP7 | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100783947, COSV100784423; called by muse, mutect2, varscan2
- ZIC1 | c.790C>A p.P264T | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99291441; called by muse, mutect2, varscan2
- ZNF304 | c.1404T>G p.I468M | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99988352; called by muse, mutect2, varscan2
- ZNF418 | c.333G>C p.R111S | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.916); catalogued as COSV101268879, COSV101268988; called by muse, mutect2, varscan2
- ZNF451 | c.1983T>A p.N661K | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.036); catalogued as COSV100674552; called by muse, mutect2, varscan2
- ZNF479 | c.1241G>A p.C414Y | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV100482423, COSV100482581; called by mutect2, varscan2
- ZNF681 | c.779G>T p.S260I | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV101267389; called by muse, mutect2, varscan2
- ZNF774 | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV100586180; called by muse, mutect2, varscan2
- ZNF875 | c.1023G>T p.K341N | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV100183007; called by muse, mutect2, varscan2
- ZSCAN1 | c.521G>A p.S174N | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.062); catalogued as COSV99991283; called by muse, mutect2, varscan2
- ZSCAN2 | c.1031G>T p.G344V | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.19); catalogued as COSV100306784; called by muse, mutect2, varscan2
- ANXA11 | c.189del p.T64Hfs*87 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | called by mutect2, pindel, varscan2
- AQP12B | c.536C>T p.A179V (on ENST00000621682; = p.A191V on NM_001102467.2) | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CLASP1 | c.719del p.N240Ifs*72 | Frame Shift Del (DEL) | VAF 23/126 reads (18%) | called by mutect2, pindel, varscan2
- CNGB1 | c.2111_2128del p.L704_F709del | In Frame Del (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- GSTP1 | c.221del p.G74Afs*20 | Frame Shift Del (DEL) | VAF 18/156 reads (12%) | called by mutect2, varscan2
- IGHV1OR15-9 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- IGKV1D-16 | c.55+1del | Frame Shift Del (DEL) | VAF 34/194 reads (18%) | called by mutect2, varscan2
- JUND | c.463_479del p.A155Rfs*263 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | called by mutect2, varscan2
- MARVELD2 | c.1084_1088del p.C362Kfs*6 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- MYO19 | c.476G>T p.W159L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAB43 | c.549del p.H184Tfs*16 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | called by mutect2, pindel, varscan2
- SALL1 | c.3304_3312del p.D1102_P1104del | In Frame Del (DEL) | VAF 9/55 reads (16%) | called by mutect2, pindel, varscan2
- SPTA1 | c.4993del p.D1665Tfs*2 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | called by mutect2, pindel, varscan2
- SPTA1 | c.3543del p.S1181Rfs*59 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- ABCA13 | c.13545C>A p.V4515= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV101291169; called by muse, mutect2, varscan2
- ADGRE3 | c.186G>A p.L62= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs202239062, COSV99505753, COSV99506080; called by muse, mutect2, varscan2
- ADGRF2 | c.1113C>A p.P371= (on ENST00000296862 / NM_001368115.2; = p.P303= on NM_153839.7) | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as COSV99730612; called by muse, mutect2, varscan2
- APBB1IP | c.1920C>A p.P640= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs772784067, COSV66130472; called by muse, mutect2, varscan2
- BBS7 | c.540G>A p.V180= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV99144798; called by muse, mutect2, varscan2
- BLZF1 | c.1176C>T p.H392= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100250472; called by muse, mutect2, varscan2
- BRD2 | c.246A>G p.L82= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as rs776515671, COSV100875547; called by muse, mutect2, varscan2
- COL3A1 | c.3126C>A p.A1042= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as COSV100482349; called by muse, mutect2, varscan2
- DAG1 | c.1101G>A p.T367= | Silent (SNP) | VAF 33/134 reads (25%) | catalogued as rs142406476, COSV100445143; called by muse, mutect2, varscan2
- DISP3 | c.1746C>A p.S582= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV99607184; called by muse, mutect2, varscan2
- DNAH10 | c.9234C>A p.V3078= (on ENST00000409039; = p.V3017= on NM_207437.3) | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV101291908; called by muse, mutect2, varscan2
- FAM151A | c.258G>A p.L86= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as rs756626093, COSV100156712; called by muse, mutect2, varscan2
- FAM193A | c.3207C>T p.A1069= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV100218474; called by muse, mutect2
- FBXO24 | c.186C>T p.L62= (on ENST00000241071 / NM_033506.3; = p.L100= on NM_012172.5) | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as rs1240648482; called by muse, mutect2
- FCRL3 | c.648T>C p.S216= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as COSV100942763; called by muse, mutect2, varscan2
- GAS2L2 | c.2422A>C p.R808= | Silent (SNP) | VAF 34/121 reads (28%) | called by muse, mutect2, varscan2
- GCG | c.516T>A p.I172= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100972708; called by muse, mutect2, varscan2
- GRM3 | c.2616C>A p.L872= | Silent (SNP) | VAF 25/129 reads (19%) | catalogued as COSV100862049, COSV64470591; called by muse, mutect2, varscan2
- H2BC9 | c.69G>A p.Q23= | Silent (SNP) | VAF 31/173 reads (18%) | catalogued as COSV55099778, COSV55099825; called by muse, mutect2, varscan2
- HRH3 | c.555G>A p.E185= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV100420418, COSV100420575; called by muse, mutect2, varscan2
- HTR1A | c.123G>A p.L41= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV100108879; called by muse, mutect2, varscan2
- IARS2 | c.2952A>G p.K984= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV100228055; called by muse, mutect2, varscan2
- IL1R1 | c.1368A>G p.R456= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV99292323; called by muse, mutect2, varscan2
- KRT3 | c.921G>A p.L307= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100526863; called by muse, mutect2, varscan2
- LTC4S | c.201C>G p.L67= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs758359505; called by muse, mutect2
- MAPK10 | c.210G>T p.A70= (on ENST00000359221 / NM_001351625.2; = p.A108= on NM_002753.5) | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100173668; called by muse, mutect2, varscan2
- MPV17L2 | c.354C>T p.F118= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV99717889; called by muse, mutect2
- MX1 | c.1428G>C p.V476= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV99912425; called by muse, mutect2, varscan2
- NAPRT | c.510G>T p.L170= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as COSV52788260, COSV99434225; called by muse, mutect2, varscan2
- NDST4 | c.1305A>G p.A435= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV99995313; called by muse, mutect2, varscan2
- NECTIN4 | c.861G>A p.G287= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV100919804; called by muse, mutect2, varscan2
- NOTCH4 | c.4416G>A p.R1472= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as rs1243979329, COSV100900327; called by muse, mutect2
- NTRK1 | c.1875G>A p.G625= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV100693111; called by muse, mutect2, varscan2
- OR10AG1 | c.90G>A p.L30= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV56635283; called by muse, mutect2, varscan2
- OR2T1 | c.453C>G p.G151= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as COSV100822245; called by muse, mutect2, varscan2
- OR4B1 | c.24T>A p.T8= | Silent (SNP) | VAF 5/83 reads (6%) | catalogued as COSV100535471; called by muse, mutect2
- PCDHB1 | c.909A>G p.L303= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs898574414, COSV100128008; called by muse, mutect2, varscan2
- PGR | c.238C>T p.L80= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV99677344; called by muse, mutect2, varscan2
- PKHD1 | c.5964C>T p.I1988= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as COSV100580906, COSV104417469; called by muse, mutect2, varscan2
- PLK1 | c.375C>T p.F125= | Silent (SNP) | VAF 34/121 reads (28%) | catalogued as COSV100266907, COSV55624701; called by muse, mutect2, varscan2
- PRAMEF4 | c.159C>T p.A53= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as rs1281743549, COSV52439342, COSV99339411; called by muse, mutect2, varscan2
- PRICKLE1 | c.804C>T p.D268= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs371149992; called by muse, mutect2, varscan2
- PRSS58 | c.393C>T p.T131= | Silent (SNP) | VAF 49/220 reads (22%) | catalogued as COSV101616079; called by muse, mutect2, varscan2
- RPL10L | c.178C>T p.L60= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV100022363; called by muse, mutect2, varscan2
- SERPINC1 | c.132G>T p.P44= | Silent (SNP) | VAF 58/184 reads (32%) | catalogued as COSV100874990, COSV62928881; called by muse, mutect2, varscan2
- SLC22A1 | c.609G>A p.L203= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as COSV100266350; called by muse, mutect2, varscan2
- SLC9A2 | c.1692C>T p.A564= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV99295799; called by muse, mutect2, varscan2
- TERB2 | c.549G>A p.K183= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs1384942007, COSV100546495, COSV61650556; called by muse, mutect2, varscan2
- THRAP3 | c.2316A>G p.R772= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100663147; called by muse, mutect2, varscan2
- TLN1 | c.6273G>T p.L2091= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV100147237; called by muse, mutect2, varscan2
- TMEM169 | c.474C>A p.P158= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as COSV99824331; called by muse, mutect2, varscan2
- TNR | c.669C>T p.S223= | Silent (SNP) | VAF 59/217 reads (27%) | catalogued as rs1032289234, COSV54878193; called by muse, mutect2, varscan2
- TPP2 | c.2037G>T p.S679= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV101060144; called by muse, mutect2, varscan2
- TTN | c.47256C>A p.P15752= (on ENST00000591111; = p.P8328= on NM_003319.4) | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV100592212; called by muse, mutect2, varscan2
- TTN | c.39825A>G p.P13275= (on ENST00000591111; = p.P5851= on NM_003319.4) | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as COSV100592213; called by muse, mutect2, varscan2
- U2AF2 | c.906C>T p.Y302= | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as rs752141516, COSV100454059; called by muse, mutect2, varscan2
- VPS39 | c.852C>T p.P284= (on ENST00000348544 / NM_001301138.2; = p.P273= on NM_015289.5) | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as COSV100528918; called by muse, mutect2, varscan2
- ZNF157 | c.1173T>C p.C391= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV100998428; called by muse, mutect2, varscan2
- ZNF208 | c.2076C>A p.P692= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV101236720; called by muse, varscan2
- ZNF460 | c.1164A>C p.G388= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV100828015; called by muse, mutect2, varscan2
- ANKRD13D | c.*455C>T | 3'UTR (SNP) | VAF 12/110 reads (11%) | catalogued as rs779191140, COSV100398230; called by muse, mutect2, varscan2
- DDX41 | c.*469A>G | 3'UTR (SNP) | VAF 50/181 reads (28%) | catalogued as COSV100394181; called by muse, mutect2, varscan2
- FOLH1B | n.850T>C | RNA (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
- GLRX5 | chr14:95533542 C>A | 5'Flank (SNP) | VAF 32/119 reads (27%) | called by muse, mutect2, varscan2
- KLK3 | c.631-369G>A | Intron (SNP) | VAF 26/101 reads (26%) | catalogued as COSV100385852; called by muse, mutect2, varscan2
- SLC35E2A | n.965G>T | RNA (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99870633; called by muse, mutect2
- SMIM12 | chr1:34855207 G>A | 3'Flank (SNP) | VAF 30/110 reads (27%) | catalogued as rs1159709239, COSV101315043; called by muse, mutect2, varscan2
- SNORD115-7 | n.29A>G | RNA (SNP) | VAF 59/404 reads (15%) | called by muse, mutect2, varscan2
- SNORD116-26 | n.83G>T | RNA (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- ZNF37A | c.*2G>T | 3'UTR (SNP) | VAF 17/41 reads (41%) | catalogued as COSV100697249; called by muse, mutect2, varscan2
